Gene-level copy-number profile of tumor specimen C3N-03839-01 (profiled together with C3N-03839-02, C3N-03839-05) from CPTAC case C3N-03839, project CPTAC-3 (Pancreas — Ductal and Lobular Neoplasms). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 54.6 years (19,956 days).
Specimen C3N-03839-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file a66780f9-167c-493e-8afa-b3ab2601e330.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-03839-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,224 have no estimate.
https://portal.gdc.cancer.gov/files/6861816e-8b22-47bc-9870-d70a0f3ef223

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 2: 10,304; copy number 3: 291; copy number 4: 39,746; copy number 5: 21; copy number 6: 4,898; copy number 7: 2,355; copy number 8: 594; copy number 10: 18; copy number 11: 40; copy number 12: 2; copy number 13: 130.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 190 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:31,268,749–32,445,046, 132 genes, copy number 12–13 (broad region; genes not listed).
- chr6:43,722,786–46,080,348, 40 genes, copy number 11: AL136131.2, VEGFA, AL136131.3, LINC02537, AL157371.1, AL109615.3, C6orf223, AL109615.2, AL109615.1, MRPL14, TMEM63B, CAPN11, RN7SL811P, MYMX, SLC29A1, HSP90AB1, SLC35B2, MIR4647, NFKBIE, TMEM151B, AL353588.1, TCTE1, AARS2, SPATS1, CDC5L, MIR4642, AL136140.1, AL136140.2, AL133334.1, SUPT3H, NUDT19P4, AL138880.2, RBM22P4, AL138880.1, MIR586, RUNX2, AL096865.1, RUNX2-AS1, CLIC5, RNU6-754P.
- chr20:20,721,187–21,425,041, 18 genes, copy number 10: LLPHP1, RN7SL607P, MRPS11P1, AL133465.1, LINC00237, AL121759.2, RPL24P2, KIZ, RNA5SP477, AL121759.1, KIZ-AS1, RPS15AP1, ZNF877P, AL117332.1, XRN2, NKX2-4, AL158013.1, RN7SKP140.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
